Somatic mutation profile of tumor specimen TCGA-14-1795-01A (aliquot TCGA-14-1795-01A-01W-0643-08) from TCGA case TCGA-14-1795, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 66.7 years (24,375 days).
Specimen TCGA-14-1795-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 74968bc7-2363-4b36-b208-e0852b2ac7b3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-14-1795-10A (Blood Derived Normal), aliquot TCGA-14-1795-10A-01W-0643-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a5401e43-fa8c-4765-88a1-c5bd0dc20b37

The open-access MAF lists 208 somatic variants for this specimen: 142 protein-altering or splice-affecting, 61 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 112, Silent 61, Nonsense Mutation 12, Splice Site 5, Frame Shift Del 4, In Frame Del 4, Frame Shift Ins 3, Intron 2, Splice Region 2, 5'UTR 1, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.44G>A p.R15K | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs398123324, COSV100910708, COSV64297317, COSV64299553; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.923A>G p.N308S | Missense Mutation (SNP) | VAF 19/180 reads (11%) | hotspot (GDC flag); SIFT tolerated (0.07); PolyPhen benign (0.042); catalogued as rs121918455, CM021135, CM044252, COSV61006976, COSV61014185; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.731G>A p.G244D | Missense Mutation (SNP) | VAF 232/417 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs985033810, CM056069, CM070298, COSV52661058, COSV52724858, COSV52839584; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCG2 | c.337C>T p.R113* | Nonsense Mutation (SNP) | VAF 41/102 reads (40%) | catalogued as rs201121511, CM136592, COSV99420449; called by muse, mutect2, varscan2
- ABCG5 | c.7G>A p.D3N | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as COSV99575722; called by muse, mutect2, varscan2
- ADGRF5 | c.2993C>T p.S998F | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99346650; called by muse, mutect2, varscan2
- AGFG2 | c.1271dup p.Q425Afs*138 | Frame Shift Ins (INS) | VAF 5/44 reads (11%) | catalogued as rs745530680; called by pindel, varscan2
- AGPAT3 | c.768-1G>A p.X256_splice | Splice Site (SNP) | VAF 7/46 reads (15%) | catalogued as COSV99377918; called by muse, mutect2, varscan2
- AMY2B | c.1454C>T p.S485F | Missense Mutation (SNP) | VAF 55/353 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as COSV100796556; called by muse, mutect2, varscan2
- ANPEP | c.1571C>T p.A524V | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.144); catalogued as COSV100263638; called by muse, mutect2
- ARMC12 | c.162C>A p.A54= | Splice Region (SNP) | VAF 5/86 reads (6%) | catalogued as COSV99849652; called by muse, mutect2
- ARRDC3 | c.827C>T p.S276F | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99475416; called by muse, mutect2, varscan2
- ASB5 | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.704); catalogued as COSV99641413; called by muse, varscan2
- ATM | c.3379G>A p.A1127T | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV53752615, COSV99592482; called by muse, mutect2, varscan2
- BSDC1 | c.1156+1G>A p.X386_splice | Splice Site (SNP) | VAF 89/414 reads (21%) | catalogued as COSV61983115; called by muse, mutect2, varscan2
- CAVIN2 | c.896G>A p.R299Q | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.091); catalogued as rs760185073, COSV100414406; called by muse, mutect2, varscan2
- CBLB | c.1380G>A p.M460I | Missense Mutation (SNP) | VAF 4/74 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV99914645; called by muse, mutect2
- CD36 | c.475A>C p.N159H | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as COSV99988084; called by muse, mutect2, varscan2
- CFAP53 | c.898C>T p.Q300* | Nonsense Mutation (SNP) | VAF 81/505 reads (16%) | catalogued as COSV101275051; called by muse, mutect2, varscan2
- CFAP54 | c.5005G>A p.D1669N | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.904); catalogued as COSV100733231, COSV100733429; called by muse, mutect2, varscan2
- CHST15 | c.907G>A p.G303R | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.97); catalogued as COSV100655420; called by muse, mutect2, varscan2
- COL4A3 | c.2507G>A p.G836E | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM108984, COSV101170635, COSV67412347; called by muse, mutect2, varscan2
- CUL9 | c.5464G>A p.E1822K | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.948); catalogued as COSV99336207; called by muse, mutect2, varscan2
- CYP7B1 | c.458T>A p.L153H | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100043266; called by muse, mutect2, varscan2
- DCC | c.3764C>T p.T1255M | Missense Mutation (SNP) | VAF 35/243 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs775848107, COSV101473552, COSV71434183; called by muse, mutect2, varscan2
- DENND2C | c.2400A>T p.E800D (on ENST00000393274 / NM_001256404.2; = p.E743D on NM_198459.4) | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.38); PolyPhen benign (0.022); catalogued as COSV101283986; called by muse, mutect2, varscan2
- DENND2C | c.2399A>T p.E800V (on ENST00000393274 / NM_001256404.2; = p.E743V on NM_198459.4) | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV101283987; called by muse, mutect2, varscan2
- DENND2C | c.226C>T p.R76C | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs759871325, COSV101283988; called by muse, varscan2
- DMP1 | c.1206G>T p.E402D | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as COSV99219092; called by muse, mutect2, varscan2
- DNAJC13 | c.6596C>T p.S2199F | Missense Mutation (SNP) | VAF 31/484 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); catalogued as COSV99608376; called by muse, mutect2
- DUS4L-BCAP29 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.388); catalogued as COSV99143789; called by muse, mutect2, varscan2
- DUSP12 | c.481C>T p.Q161* | Nonsense Mutation (SNP) | VAF 13/55 reads (24%) | catalogued as COSV100909787; called by muse, mutect2, varscan2
- EDEM1 | c.1901A>C p.D634A | Missense Mutation (SNP) | VAF 24/174 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.122); catalogued as rs767494012; called by mutect2, varscan2
- EPHX1 | c.1013G>A p.R338Q | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.378); catalogued as rs1451067258, COSV99689278; called by muse, mutect2
- ERGIC3 | c.814G>A p.A272T | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated (0.43); PolyPhen benign (0.328); catalogued as rs777174525, COSV99481950, COSV99482041; called by muse, mutect2, varscan2
- FANCB | c.113C>T p.T38I | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.051); catalogued as COSV100146722; called by muse, varscan2
- FBN1 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.79); PolyPhen benign (0.014); catalogued as COSV100356642; called by muse, mutect2, varscan2
- FKBP3 | c.16C>T p.P6S | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as COSV53533552; called by muse, varscan2
- FLG | c.10970G>A p.R3657Q | Missense Mutation (SNP) | VAF 68/600 reads (11%) | SIFT tolerated (0.58); PolyPhen benign (0.045); catalogued as rs201687214; called by muse, varscan2
- FLG2 | c.4598A>G p.E1533G | Missense Mutation (SNP) | VAF 112/639 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs778864641, COSV101166315; called by muse, varscan2
- FLG2 | c.4148C>T p.T1383I | Missense Mutation (SNP) | VAF 124/315 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.403); catalogued as COSV101166316; called by muse, varscan2
- GABRE | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 55/282 reads (20%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.996); catalogued as rs374701075, COSV100944426; called by muse, mutect2, varscan2
- GATM | c.238G>A p.V80M | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101188455; called by muse, mutect2, varscan2
- GCKR | c.1144-1G>A p.X382_splice | Splice Site (SNP) | VAF 12/90 reads (13%) | catalogued as rs373986830; called by muse, varscan2
- GRIN2A | c.2536C>T p.R846C | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1285952756, COSV58018457, COSV58033091; called by muse, mutect2, varscan2
- GRIN2B | c.267G>T p.M89I | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as COSV101663228; called by muse, mutect2, varscan2
- GRIP1 | c.2000C>T p.S667F (on ENST00000359742 / NM_001379345.1; = p.S615F on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/110 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.434); catalogued as COSV99671433; called by muse, varscan2
- GRIP1 | c.727T>C p.S243P | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.177); catalogued as COSV99671434; called by muse, mutect2, varscan2
- HJURP | c.1842G>A p.M614I | Missense Mutation (SNP) | VAF 41/208 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV100982654; called by muse, mutect2, varscan2
- HNRNPL | c.1555G>A p.E519K | Missense Mutation (SNP) | VAF 62/122 reads (51%) | SIFT tolerated (0.51); PolyPhen benign (0.034); catalogued as COSV99670126, COSV99670671; called by muse, varscan2
- HRNR | c.2971C>T p.R991C | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs373485996, COSV64258660; called by muse, mutect2, varscan2
- HUWE1 | c.12476A>T p.Y4159F | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.956); catalogued as COSV99474875; called by mutect2, varscan2
- IL1RL2 | c.872G>T p.R291L | Missense Mutation (SNP) | VAF 84/243 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.013); catalogued as COSV99961207; called by muse, mutect2, varscan2
- ITGB2 | c.322C>T p.R108* | Nonsense Mutation (SNP) | VAF 17/134 reads (13%) | catalogued as rs772471533, BM1528049, COSV100186209; called by muse, mutect2, varscan2
- ITM2A | c.315G>T p.E105D | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT tolerated (0.17); PolyPhen benign (0.067); catalogued as COSV100964503; called by muse, mutect2, varscan2
- KAT14 | c.1864C>T p.H622Y | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100890129; called by muse, varscan2
- LAMA2 | c.3803C>T p.S1268F | Missense Mutation (SNP) | VAF 39/189 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.023); catalogued as rs776042035; ClinVar: uncertain significance; called by muse, varscan2
- LMLN | c.739G>A p.G247R | Missense Mutation (SNP) | VAF 80/245 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100218978; called by muse, varscan2
- LMLN | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 93/272 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100218980; called by muse, varscan2
- LRCH3 | c.1610G>A p.R537K | Missense Mutation (SNP) | VAF 37/230 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.817); catalogued as COSV100605312, COSV58388315; called by muse, mutect2, varscan2
- LRRC15 | c.1303C>T p.R435C | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs552954426, COSV61652061; called by muse, mutect2, varscan2
- LRRC66 | c.1794G>C p.Q598H | Missense Mutation (SNP) | VAF 13/246 reads (5%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.753); catalogued as rs908256959, COSV100603128, COSV100603144; called by muse, mutect2
- LRRFIP2 | c.1799G>A p.R600K | Missense Mutation (SNP) | VAF 47/215 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs762677172, COSV100368771; called by muse, mutect2, varscan2
- MAS1 | c.178C>T p.R60W | Missense Mutation (SNP) | VAF 20/616 reads (3%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.863); catalogued as rs919590114, COSV53121510; called by muse, mutect2
- MEGF10 | c.1705G>A p.D569N | Missense Mutation (SNP) | VAF 67/297 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV57252740, COSV99175898; called by muse, mutect2, varscan2
- METTL1 | c.426G>A p.M142I | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as COSV99141682; called by muse, mutect2
- MORC4 | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 74/152 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99717778; called by muse, mutect2, varscan2
- MRGPRD | c.56G>A p.R19K | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100483111; called by muse, mutect2, varscan2
- MSL3 | c.841C>T p.Q281* (on ENST00000312196 / NM_078629.4; = p.Q115* on NM_006800.4) | Nonsense Mutation (SNP) | VAF 65/75 reads (87%) | catalogued as COSV100385120, COSV56494234; called by muse, mutect2, varscan2
- MTR | c.3214G>A p.D1072N | Missense Mutation (SNP) | VAF 52/104 reads (50%) | SIFT tolerated (0.28); PolyPhen benign (0.439); catalogued as COSV100855608; called by muse, varscan2
- NBPF26 | c.2293G>A p.E765K (on ENST00000620612; = p.E503K on NM_001351372.1) | Missense Mutation (SNP) | VAF 411/1026 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.444); catalogued as rs1553271801; called by muse, varscan2
- NBPF26 | c.2346G>A p.W782* (on ENST00000620612; = p.W520* on NM_001351372.1) | Nonsense Mutation (SNP) | VAF 304/874 reads (35%) | catalogued as rs1553271816; called by muse, varscan2
- NCOA3 | c.1493C>T p.S498F | Missense Mutation (SNP) | VAF 24/267 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100508455; called by muse, mutect2
- NF1 | c.755T>A p.L252* | Nonsense Mutation (SNP) | VAF 21/74 reads (28%) | catalogued as CD000952, CM1512910, COSV100648510, COSV100648612; called by muse, mutect2, varscan2
- NIF3L1 | c.842C>A p.A281D (on ENST00000409020 / NM_001369444.1; = p.A254D on NM_021824.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/135 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV100677632; called by muse, mutect2
- NLGN2 | c.1657C>T p.Q553* | Nonsense Mutation (SNP) | VAF 10/28 reads (36%) | catalogued as COSV100081331; called by muse, mutect2, varscan2
- NOS3 | c.2194C>T p.R732C | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV99872336; called by muse, mutect2, varscan2
- NUP210L | c.2312T>C p.V771A | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV99669362; called by muse, mutect2, varscan2
- OGA | c.2269G>A p.G757R | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63382477; called by muse, mutect2, varscan2
- OR13C2 | c.718A>T p.T240S | Missense Mutation (SNP) | VAF 23/209 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101604894; called by muse, mutect2, varscan2
- OR1S1 | c.238T>C p.S80P | Missense Mutation (SNP) | VAF 128/447 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV100515523; called by muse, mutect2, varscan2
- OR4C16 | c.91C>T p.R31C | Missense Mutation (SNP) | VAF 86/164 reads (52%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs768595930, COSV58940480; called by muse, mutect2, varscan2
- OR7G2 | c.5C>T p.P2L | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs368281058; called by muse, mutect2, varscan2
- OR8K1 | c.205del p.R70Dfs*19 | Frame Shift Del (DEL) | VAF 47/374 reads (13%) | catalogued as COSV54401320; called by mutect2, pindel, varscan2
- PALM2AKAP2 | c.2221C>T p.Q741* (on ENST00000259318 / NM_001136562.3; = p.Q972* on NM_007203.5) | Nonsense Mutation (SNP) | VAF 13/26 reads (50%) | catalogued as COSV99395916; called by muse, mutect2, varscan2
- PCDH7 | c.203T>C p.L68P | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100688765; called by muse, mutect2, varscan2
- PHTF1 | c.47T>G p.I16S | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV99793679; called by muse, mutect2, varscan2
- PIWIL2 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 54/354 reads (15%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as rs773382709, COSV100769599; called by muse, varscan2
- PLCB1 | c.2056C>T p.Q686* | Nonsense Mutation (SNP) | VAF 10/40 reads (25%) | catalogued as COSV100572516; called by muse, mutect2, varscan2
- PSMD5 | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 32/48 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV52961866; called by muse, mutect2, varscan2
- PYCARD | c.317C>T p.S106L | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs758894522, COSV99910990; called by muse, mutect2, varscan2
- RAB3GAP1 | c.2804C>T p.A935V | Missense Mutation (SNP) | VAF 181/569 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs1162339580, COSV99921978; called by muse, mutect2, varscan2
- RIN3 | c.366G>A p.S122= | Splice Region (SNP) | VAF 119/157 reads (76%) | catalogued as rs373178052; called by muse, varscan2
- RTCB | c.460G>A p.G154R | Missense Mutation (SNP) | VAF 16/291 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99322474; called by muse, mutect2
- SLC6A4 | c.820G>A p.V274I | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.683); catalogued as rs746585288, COSV99911543; called by muse, mutect2, varscan2
- SLCO4C1 | c.1811G>T p.R604M | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100196045; called by muse, mutect2, varscan2
- SLFN13 | c.1057G>A p.A353T | Missense Mutation (SNP) | VAF 39/179 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs541429130, COSV53196334; called by muse, mutect2, varscan2
- SLITRK6 | c.2130A>T p.E710D | Missense Mutation (SNP) | VAF 29/196 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101233315; called by muse, mutect2, varscan2
- SMARCC1 | c.1300T>G p.S434A | Missense Mutation (SNP) | VAF 86/132 reads (65%) | SIFT tolerated (0.55); PolyPhen benign (0.065); catalogued as COSV99593647; called by muse, mutect2, varscan2
- SMPD3 | c.1138G>A p.G380S | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs527500418, COSV99546172; called by muse, mutect2, varscan2
- SP110 | c.1417G>A p.G473R | Missense Mutation (SNP) | VAF 126/225 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99283908; called by muse, mutect2, varscan2
- SPINT2 | c.403G>A p.A135T | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.468); catalogued as rs1429365071, COSV100007711; called by muse, mutect2, varscan2
- SPRR3 | c.301G>A p.V101I | Missense Mutation (SNP) | VAF 40/205 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.018); catalogued as rs766535046, COSV99768831; called by muse, varscan2
- TAF3 | c.2733G>C p.K911N | Missense Mutation (SNP) | VAF 19/26 reads (73%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as COSV100720591; called by muse, mutect2, varscan2
- TBC1D2 | c.602C>T p.P201L | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.069); catalogued as COSV100580265; called by muse, varscan2
- TBL2 | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370483599; called by muse, mutect2, varscan2
- TGM2 | c.383C>T p.S128F | Missense Mutation (SNP) | VAF 56/108 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); catalogued as COSV100821814; called by muse, varscan2
- THRAP3 | c.2646+1G>T p.X882_splice | Splice Site (SNP) | VAF 84/417 reads (20%) | catalogued as COSV100663692; called by muse, mutect2, varscan2
- TRIM13 | c.277G>A p.V93I | Missense Mutation (SNP) | VAF 389/574 reads (68%) | SIFT tolerated (0.32); PolyPhen benign (0.185); catalogued as rs557569191, COSV53951887; called by muse, mutect2, varscan2
- TRIM45 | c.227C>T p.S76L | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as COSV99868814; called by muse, mutect2, varscan2
- TRIO | c.2090A>G p.D697G | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.977); catalogued as COSV100711149; called by muse, mutect2
- TRIP13 | c.931G>A p.D311N | Missense Mutation (SNP) | VAF 12/200 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99386601; called by muse, mutect2
- TRPV6 | c.961A>T p.T321S | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.169); catalogued as COSV100844490; called by muse, mutect2, varscan2
- TSPAN14 | c.541G>C p.G181R | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99627957; called by muse, mutect2, varscan2
- TYRO3 | c.1519A>T p.K507* | Nonsense Mutation (SNP) | VAF 26/147 reads (18%) | catalogued as COSV99778305; called by muse, mutect2
- UBAP1 | c.1232G>A p.R411K | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as COSV99903674; called by muse, mutect2
- UGT3A1 | c.1483C>A p.L495I | Missense Mutation (SNP) | VAF 35/62 reads (56%) | SIFT tolerated (0.25); PolyPhen benign (0.034); catalogued as COSV57101326, COSV99955474; called by muse, mutect2, varscan2
- USH2A | c.14917G>A p.V4973M | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs201426385; called by muse, mutect2, varscan2
- USP26 | c.1561C>T p.L521F | Missense Mutation (SNP) | VAF 63/87 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100896784; called by muse, mutect2, varscan2
- ZNF169 | c.1694C>T p.S565F | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.366); catalogued as rs1471537026, COSV100566422; called by muse, varscan2
- ZNF2 | c.761G>A p.R254H (on ENST00000611147 / NM_001291605.2; = p.R241H on NM_021088.4) | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.861); catalogued as rs748221475, COSV99728770; called by muse, mutect2, varscan2
- ZNF343 | c.848C>T p.T283I | Missense Mutation (SNP) | VAF 210/338 reads (62%) | SIFT tolerated (0.26); PolyPhen benign (0.14); catalogued as COSV99601728; called by muse, mutect2, varscan2
- ZNF655 | c.37_38insA p.P13Hfs*13 | Frame Shift Ins (INS) | VAF 55/215 reads (26%) | catalogued as COSV99402416; called by mutect2, pindel, varscan2
- AGAP1 | c.170T>C p.F57S | Missense Mutation (SNP) | VAF 94/694 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by mutect2, varscan2
- DNAJC1 | c.512G>A p.W171* | Nonsense Mutation (SNP) | VAF 9/60 reads (15%) | called by mutect2, varscan2
- EPN2 | c.1127C>T p.S376L | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.03); called by mutect2, varscan2
- ERG | c.407_409del p.A136del | In Frame Del (DEL) | VAF 16/116 reads (14%) | called by pindel, varscan2
- FLG | c.10106_10107dup p.E3370Kfs*22 | Frame Shift Ins (INS) | VAF 26/210 reads (12%) | called by pindel, varscan2
- FRG2C | c.556G>A p.A186T | Missense Mutation (SNP) | VAF 14/256 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2
- HNRNPDL | c.829T>A p.C277S | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.796); called by mutect2, varscan2
- ITSN1 | c.2277C>G p.I759M | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- LOX | c.824C>T p.S275L | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); called by muse, varscan2
- MFN2 | c.533T>C p.L178P | Missense Mutation (SNP) | VAF 29/152 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by mutect2, varscan2
- NR4A1 | c.583C>T p.P195S | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.013); called by mutect2, varscan2
- PARP1 | c.1397_1399del p.T466del | In Frame Del (DEL) | VAF 13/34 reads (38%) | called by pindel, varscan2
- RECK | c.1109_1112del p.C370Lfs*9 | Frame Shift Del (DEL) | VAF 10/92 reads (11%) | called by mutect2, pindel, varscan2
- SLX4 | c.1361_1366del p.A455_E456del | In Frame Del (DEL) | VAF 9/76 reads (12%) | called by mutect2, pindel
- TADA3 | c.596G>A p.R199H | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.03); called by mutect2, varscan2
- TECPR2 | c.3779del p.P1260Hfs*60 | Frame Shift Del (DEL) | VAF 19/82 reads (23%) | called by mutect2, pindel, varscan2
- TMEM131L | c.3417del p.X1139_splice | Splice Site (DEL) | VAF 10/54 reads (19%) | called by mutect2, pindel, varscan2
- TTC39B | c.1981_1983del p.L661del | In Frame Del (DEL) | VAF 10/44 reads (23%) | called by mutect2, pindel, varscan2
- ZSCAN20 | c.225_229del p.C76Sfs*28 | Frame Shift Del (DEL) | VAF 20/76 reads (26%) | called by mutect2, pindel, varscan2
- ADAMTS10 | c.747G>A p.K249= | Silent (SNP) | VAF 118/798 reads (15%) | catalogued as COSV54352340; called by muse, mutect2, varscan2
- ARHGAP31 | c.675G>A p.E225= | Silent (SNP) | VAF 11/185 reads (6%) | catalogued as COSV51801105; called by muse, mutect2
- BTBD16 | c.1434G>A p.T478= | Silent (SNP) | VAF 75/187 reads (40%) | catalogued as rs764234548, COSV99585380; called by muse, mutect2, varscan2
- CAD | c.6006G>A p.Q2002= | Silent (SNP) | VAF 20/38 reads (53%) | catalogued as COSV99256055; called by muse, varscan2
- CALCOCO2 | c.45G>A p.L15= | Silent (SNP) | VAF 59/146 reads (40%) | catalogued as COSV99364000; called by muse, mutect2, varscan2
- CCDC171 | c.2655C>T p.D885= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as rs779856240, COSV52636190; called by muse, mutect2, varscan2
- CPED1 | c.1572G>A p.L524= | Silent (SNP) | VAF 4/50 reads (8%) | catalogued as COSV100121170, COSV100121732; called by muse, mutect2
- CTTNBP2 | c.3204C>T p.F1068= | Silent (SNP) | VAF 28/122 reads (23%) | catalogued as rs766973640, COSV99355122; called by muse, mutect2, varscan2
- CUL7 | c.4545C>T p.H1515= | Silent (SNP) | VAF 23/43 reads (53%) | catalogued as rs374026887; called by muse, mutect2, varscan2
- CYP2R1 | c.1441C>T p.L481= | Silent (SNP) | VAF 33/383 reads (9%) | catalogued as COSV100585025; called by muse, mutect2
- CYP7B1 | c.1323G>A p.P441= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as rs201281307, COSV100042659; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- DHCR24 | c.798C>T p.F266= | Silent (SNP) | VAF 18/128 reads (14%) | catalogued as rs142421002; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DYNC1I1 | c.144C>T p.D48= | Silent (SNP) | VAF 15/92 reads (16%) | catalogued as rs184726667; called by muse, mutect2, varscan2
- FBXW9 | c.1104C>T p.Y368= (on ENST00000587955; = p.Y348= on NM_032301.3) | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as rs1386841482, COSV100982083; called by muse, mutect2
- GEMIN2 | c.789C>T p.I263= | Silent (SNP) | VAF 17/122 reads (14%) | catalogued as COSV99158560; called by muse, mutect2, varscan2
- GMEB2 | c.276C>T p.Y92= | Silent (SNP) | VAF 10/170 reads (6%) | catalogued as COSV99823929; called by muse, mutect2
- GPR162 | c.183C>T p.L61= | Silent (SNP) | VAF 24/239 reads (10%) | catalogued as COSV99163977; called by muse, mutect2, varscan2
- GRIN2A | c.588G>C p.V196= | Silent (SNP) | VAF 352/583 reads (60%) | catalogued as COSV100410945, COSV100411387, COSV58025205; called by muse, mutect2, varscan2
- GSK3B | c.567G>A p.L189= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as rs1349074851, COSV99955869; called by mutect2, varscan2
- GUCY2D | c.1395C>T p.L465= | Silent (SNP) | VAF 27/81 reads (33%) | catalogued as rs745618018, COSV99644385; called by muse, mutect2, varscan2
- HAL | c.1767C>A p.P589= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as COSV99701712; called by muse, mutect2
- IFNA16 | c.369G>A p.V123= | Silent (SNP) | VAF 94/823 reads (11%) | catalogued as COSV101207098; called by muse, mutect2
- IL4I1 | c.403C>T p.L135= | Silent (SNP) | VAF 46/141 reads (33%) | catalogued as COSV100352440; called by muse, mutect2, varscan2
- IL6R | c.546G>A p.E182= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as COSV100691209; called by muse, mutect2, varscan2
- KIF11 | c.3159G>A p.Q1053= | Silent (SNP) | VAF 23/82 reads (28%) | catalogued as rs774629346, COSV99586232; called by muse, mutect2, varscan2
- KRTAP27-1 | c.270C>T p.S90= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as COSV101239800; called by muse, mutect2, varscan2
- LRIG2 | c.2583G>A p.T861= | Silent (SNP) | VAF 79/102 reads (77%) | catalogued as rs375045494; called by muse, mutect2, varscan2
- LY75 | c.2898C>T p.I966= | Silent (SNP) | VAF 16/156 reads (10%) | catalogued as COSV99717182; called by muse, mutect2
- MED18 | c.507G>A p.V169= | Silent (SNP) | VAF 10/209 reads (5%) | called by muse, mutect2
- MEPE | c.948C>T p.T316= | Silent (SNP) | VAF 34/187 reads (18%) | catalogued as COSV63072738; called by muse, varscan2
- MFSD4A | c.1257C>T p.P419= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV100901747; called by muse, mutect2, varscan2
- MYO15A | c.9696C>T p.A3232= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as COSV99234904; called by muse, mutect2, varscan2
- MYO6 | c.3387C>T p.N1129= (on ENST00000369981; = p.N1119= on NM_004999.4) | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV100889444, COSV104425584; called by muse, mutect2, varscan2
- MYOG | c.393C>T p.R131= | Silent (SNP) | VAF 18/29 reads (62%) | catalogued as COSV99614169; called by muse, mutect2, varscan2
- OPN1SW | c.300C>T p.F100= | Silent (SNP) | VAF 66/239 reads (28%) | catalogued as rs753929816, COSV99975615; called by muse, varscan2
- OPN3 | c.717G>A p.Q239= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as COSV100087975; called by muse, mutect2, varscan2
- PACSIN2 | c.1077C>T p.S359= | Silent (SNP) | VAF 28/81 reads (35%) | catalogued as COSV99606815; called by muse, mutect2, varscan2
- PCDHB2 | c.1950C>T p.G650= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as rs1563830310, COSV50644110; called by muse, mutect2, varscan2
- PCK1 | c.534G>A p.T178= | Silent (SNP) | VAF 38/85 reads (45%) | catalogued as rs1394499113, COSV60127873, COSV60129940; called by muse, mutect2, varscan2
- PDK2 | c.852G>A p.L284= | Silent (SNP) | VAF 45/185 reads (24%) | catalogued as COSV99143140; called by muse, mutect2, varscan2
- PGAP4 | c.1188C>T p.Y396= | Silent (SNP) | VAF 113/357 reads (32%) | catalogued as COSV100877886, COSV66387388; called by muse, mutect2, varscan2
- PGAP4 | c.576C>T p.V192= | Silent (SNP) | VAF 18/140 reads (13%) | catalogued as COSV66388416; called by muse, varscan2
- PGR | c.1146G>T p.P382= | Silent (SNP) | VAF 14/96 reads (15%) | catalogued as rs753663386, COSV99679324; called by muse, varscan2
- PKM | c.555G>A p.V185= | Silent (SNP) | VAF 24/358 reads (7%) | catalogued as COSV100065357; called by muse, mutect2
- PLCB1 | c.2178C>T p.V726= | Silent (SNP) | VAF 17/77 reads (22%) | catalogued as rs1467802767, COSV100572518; called by muse, mutect2, varscan2
- PLCL1 | c.1405C>A p.R469= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as rs765105645, COSV70826695, COSV70873977; called by muse, mutect2, varscan2
- PLK1 | c.1152C>T p.V384= | Silent (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2
- POLD3 | c.282G>A p.V94= | Silent (SNP) | VAF 33/160 reads (21%) | catalogued as COSV55242519, COSV99738505; called by muse, mutect2, varscan2
- POU3F3 | c.1239C>T p.I413= | Silent (SNP) | VAF 31/45 reads (69%) | catalogued as rs777507294, COSV100796894; called by muse, mutect2, varscan2
- PROX1 | c.321G>A p.T107= | Silent (SNP) | VAF 28/137 reads (20%) | catalogued as rs372904856, COSV54775674, COSV54778616; called by muse, mutect2, varscan2
- RTN4RL2 | c.123G>A p.P41= | Silent (SNP) | VAF 70/137 reads (51%) | catalogued as rs199912991; called by muse, mutect2, varscan2
- SASH1 | c.1806C>T p.V602= | Silent (SNP) | VAF 27/86 reads (31%) | catalogued as rs991274312, COSV66561104; called by mutect2, varscan2
- SASH1 | c.2469G>A p.E823= | Silent (SNP) | VAF 4/37 reads (11%) | catalogued as COSV100821539; called by muse, varscan2
- SCNN1B | c.615C>T p.F205= | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as COSV56304689; called by muse, mutect2, varscan2
- SIPA1L2 | c.873C>T p.L291= | Silent (SNP) | VAF 82/218 reads (38%) | catalogued as rs373117685; called by mutect2, varscan2
- SLC5A11 | c.1566C>T p.L522= | Silent (SNP) | VAF 12/74 reads (16%) | catalogued as COSV100762981; called by muse, mutect2, varscan2
- SRP72 | c.6G>A p.A2= | Silent (SNP) | VAF 30/65 reads (46%) | catalogued as rs1433772431, COSV100714402; called by muse, varscan2
- TNRC6A | c.3804G>A p.E1268= | Silent (SNP) | VAF 35/109 reads (32%) | catalogued as rs1422057636, COSV100170643; called by muse, mutect2, varscan2
- UTP23 | c.6G>A p.K2= | Silent (SNP) | VAF 4/53 reads (8%) | called by muse, mutect2
- WNK1 | c.5109G>A p.L1703= (on ENST00000315939 / NM_018979.4; = p.L1456= on NM_014823.3) | Silent (SNP) | VAF 68/372 reads (18%) | catalogued as COSV100268927; called by muse, varscan2
- ZNF335 | c.3618C>T p.I1206= | Silent (SNP) | VAF 6/102 reads (6%) | called by muse, mutect2
- CASP10 | c.1415+8156C>T | Intron (SNP) | VAF 28/298 reads (9%) | called by mutect2, varscan2
- FAM74A3 | n.125C>A | RNA (SNP) | VAF 6/88 reads (7%) | called by muse, mutect2
- LCE4A | c.-1G>A | 5'UTR (SNP) | VAF 82/260 reads (32%) | catalogued as COSV100140099, COSV100140120; called by muse, mutect2, varscan2
- RTN3 | c.*58C>T | 3'UTR (SNP) | VAF 8/92 reads (9%) | catalogued as COSV100380436; called by muse, mutect2
- VSTM4 | c.457+3759G>T | Intron (SNP) | VAF 50/83 reads (60%) | catalogued as COSV100039421; called by muse, mutect2, varscan2
